Gene-level copy-number profile of tumor specimen TCGA-66-2793-01A from TCGA case TCGA-66-2793, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.8 years (25,111 days).
Specimen TCGA-66-2793-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.bd3acd05-38e9-409e-94d3-3c73815c5690.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2793-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/09b1a7d6-c24a-43d2-a7b7-f62f8e510745

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 1,647; copy number 2: 19,092; copy number 3: 11,015; copy number 4: 16,918; copy number 5: 7,480; copy number 6: 2,796; copy number 7: 160; copy number 8: 55; copy number 9: 114; copy number 10: 294; copy number 12: 9; copy number 14: 24; copy number 17: 77; copy number 22: 11; copy number 24: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2793-01A-01D-1195-01): tumor purity 0.85, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,513,999–34,165,842, 4 genes (within-gene range 0–2): CSMD2, HSPD1P14, HMGB4, CSMD2-AS1.
- chr9:20,999,509–23,826,337, 66 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:33,013,087–34,174,964, 1 gene (within-gene range 0–2): ASIC2.
- chr17:33,529,787–33,816,761, 8 genes: AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4.
- chr22:31,753,867–31,956,243, 2 genes (within-gene range 0–2): DEPDC5, Z82190.2.
- chr22:31,816,379–31,837,298, 2 genes: AL022331.1, RNU6-201P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11,054 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,081,316–39,487,177, 1 gene, copy number 14 (within-gene range 2–14): MACF1.
- chr1:39,226,670–93,180,516, 1,054 genes, copy number 5–22 (within-gene range 2–22) (broad region; genes not listed).
- chr1:93,190,740–93,191,060, 1 gene, copy number 5: AC126124.2.
- chr1:98,660,388–99,244,794, 5 genes, copy number 6 (within-gene range 3–6): AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1.
- chr2:4,945,277–6,003,510, 11 genes, copy number 5: RNU6-649P, AC073143.1, AC107057.1, LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810, SILC1, MIR7158.
- chr2:23,018,125–95,259,774, 1,340 genes, copy number 5–8 (within-gene range 5–10) (broad region; genes not listed).
- chr3:93,843,764–131,388,830, 649 genes, copy number 5–7 (broad region; genes not listed).
- chr3:146,192,335–198,222,513, 924 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:49,096–2,043,970, 76 genes, copy number 5–17 (broad region; genes not listed).
- chr4:19,455,418–23,904,089, 31 genes, copy number 5 (within-gene range 4–5): AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6, AC097512.1, AC092440.1, RFPL4AP3, AC093607.1, ERVH-1, PPARGC1A, AC092834.1.
- chr4:36,902,242–52,038,299, 216 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:53,377,839–54,295,272, 1 gene, copy number 5 (within-gene range 4–5): AC058822.1.
- chr4:53,592,956–54,102,498, 12 genes, copy number 5: LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2.
- chr4:54,943,626–58,118,070, 74 genes, copy number 5–7 (broad region; genes not listed).
- chr6:30,326,479–163,588,165, 2,189 genes, copy number 5–12 (broad region; genes not listed).
- chr6:163,705,937–163,714,306, 1 gene, copy number 5: AL137005.1.
- chr7:3,301,252–4,269,000, 4 genes, copy number 6–8 (within-gene range 2–8): SDK1, AC092427.1, AC011284.1, AC017000.1.
- chr7:107,923,799–108,003,213, 1 gene, copy number 6 (within-gene range 4–6): LAMB1.
- chr7:107,999,791–108,995,029, 13 genes, copy number 6: U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr8:82,033,533–84,142,463, 11 genes, copy number 5: AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1.
- chr8:143,412,749–145,066,685, 118 genes, copy number 6 (broad region; genes not listed).
- chr13:97,278,768–97,295,400, 1 gene, copy number 5 (within-gene range 3–5): AL161430.1.
- chr14:33,677,360–39,432,500, 121 genes, copy number 5–6 (broad region; genes not listed).
- chr14:54,396,849–59,576,812, 105 genes, copy number 6 (broad region; genes not listed).
- chr14:62,514,872–66,177,635, 79 genes, copy number 6–8 (broad region; genes not listed).
- chr14:92,253,493–106,875,071, 657 genes, copy number 5–6 (broad region; genes not listed).
- chr15:80,679,684–80,755,621, 1 gene, copy number 5 (within-gene range 3–5): ABHD17C.
- chr15:80,769,600–81,149,179, 14 genes, copy number 5 (within-gene range 3–5): AC023302.2, CEMIP, MIR549A, AC027808.1, AC027808.2, MESD, AC068870.1, MIR4514, AC068870.2, TLNRD1, AC068870.4, CFAP161, AC068870.3, ANP32BP3.
- chr16:11,555–21,339,037, 775 genes, copy number 6 (broad region; genes not listed).
- chr17:11,598,470–13,306,771, 24 genes, copy number 6 (within-gene range 3–6): DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1, LINC02093.
- chr17:45,263,119–83,095,122, 1,195 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr18:10,612,304–11,914,344, 36 genes, copy number 5–6: LINC01887, AP001180.3, CCDC58P1, AP001180.2, AP001180.5, PMM2P1, AP001180.1, PIEZO2, AP001180.4, KIAA0895LP1, MIR6788, AP005120.1, AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2.
- chr18:14,053,951–15,330,282, 52 genes, copy number 5: AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr18:27,335,968–30,414,073, 21 genes, copy number 5 (within-gene range 4–5): AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F.
- chr19:27,638,483–28,125,430, 15 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr20:6,731,080–36,894,235, 588 genes, copy number 5–6 (broad region; genes not listed).
- chr20:39,757,202–43,189,970, 32 genes, copy number 5–6 (within-gene range 4–6): AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT.
- chr20:42,968,743–64,313,132, 566 genes, copy number 5 (broad region; genes not listed).
- chr22:20,394,115–21,045,017, 40 genes, copy number 24: ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P.

Autosomal genes at a single copy (total copy number 1): 925. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
